CPTAC case C3L-02346 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8355bf5-6037-4f5f-a277-237a6917a23e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Dead; Days to death: 999 days (2.7 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 69.5 years (25,391 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M1; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: G4; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 999 days (2.7 years); Progression or recurrence: no; Days to last follow up: 999 days (2.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (5 entries)
- Days to follow up: 384 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 693 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 984 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 999 days (2.7 years); Disease response: Progressive Disease.
- Days to follow up: 999 days (2.7 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 93 kg; Height: 183 cm; BMI: 27.77.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 78; Cigarettes per day: 30; Tobacco smoking onset year: 1964; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 58.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02346-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 308 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02346-21: Section location: Middle; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02346-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 616 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02346-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
